Surgical pathology report (de-identified scan), TCGA case TCGA-J2-A4AE, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J2-A4AE-01A (Primary Tumor).

[page 1 of 6]
COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Source of Specimen

- A. 4R-1-
- B. 4R-2-
- C. 2R-1-
- D. 2R-2-
- E. 4L-1 - FS-
- F. 4L-2 - FS-
- G. STATION 3-
- H. 2L-1-
- I. STATION 7 - FS-
- J. HILAR NODE #1-
- K. HILAR NODE #2
- L. HILAR NODE #3-
- M. LINGULAR SEGMENT LEFT UPPER LOBE-STITCH AT MASS-
- N. LINGULAR SEGMENT LEFT UPPER LOBE FS-
- O. STATION #5-
- P. EXTENDED LINGULAR SEGMENT - STITCH AT MASS-
- Q. EXTENDED LINGULAR SEGMENT FS-

ICD-0-3

adenocarcinoma, NOS 8140/3

CQLF Site: lung, upper lobe C34.1

Path site: lung, lingula C34.1

hw
9/24/12

FINAL DIAGNOSIS:

- A. 4R-1-
LYMPH NODE, NO TUMOR SEEN.
- B. 4R-2-
LYMPH NODE, NO TUMOR SEEN.
- C. 2R-1-
LYMPH NODE, NO TUMOR SEEN.
- D. 2R-2-
LYMPH NODE, NO TUMOR SEEN.
- E. 4L-1 - FS-

Prepared

[page 2 of 6]
LYMPH NODE, NO TUMOR SEEN.
F. 4L-2 - FS-
LYMPH NODE, NO TUMOR SEEN.
G. STATION 3-
LYMPH NODE, NO TUMOR SEEN.
H. 2L-1-
LYMPH NODE, NO TUMOR SEEN.
I. STATION 7 - FS-
LYMPH NODE, NO TUMOR SEEN.
J. HILAR NODE #1-
LYMPH NODE, NO TUMOR SEEN.
K. HILAR NODE #2
LYMPH NODE, NO TUMOR SEEN.
L. HILAR NODE #3-
LYMPH NODE, NO TUMOR SEEN.
M. LINGULAR SEGMENT LEFT UPPER LOBE-STITCH AT MASS-
LUNG WITH MICROFOCUS OF ATYPICAL ADENOMATOUS HYPERPLASIA.
NO TUMOR SEEN.
N. LINGULAR SEGMENT LEFT UPPER LOBE FS-
SEE PART M.
O. STATION #5-
LYMPH NODE, NO TUMOR SEEN.
P. EXTENDED LINGULAR SEGMENT - STITCH AT MASS-
MINIMALLY INVASIVE ADENOCARCINOMA, LIMITED TO LUNG.

HISTOLOGIC GRADE: 3/4.

TUMOR FOCALITY: UNIFOVAL.

TUMOR SIZE: 1.5 CM.
THE INVASIVE COMPONENT OF THE TUMOR MEASURES 0.4 CM.

TUMOR SITE: LINGULA

VISCERAL PLEURA INVASION: NOT SEEN.

NO SIGNIFICANT OBSTRUCTIVE PNEUMONITIS OR ATELECTASIS SEEN.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

LARGE VESSEL INVASION: NOT SEEN.

LYMPH NODE INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 13

TNM STAGE: pT1a, pN0, pMX.

SPECIMEN TYPE: LINGULAR SEGMENTECTOMY.

Prepared:

[page 3 of 6]
NO TUMOR SEEN AT RESECTION MARGINS.

Q. EXTENDED LINGULAR SEGMENT FS-
SEE PART P.

Signed Others

Frozen Section

A. 4L-1, 4L-2, STATION 7: LYMPH NODES, NO TUMOR SEEN.

LINGULAR SEGMENT, LEFT UPPER LOBE: NO TUMOR SEEN.

EXTENDED LINGULAR SEGMENT: ADENOCARCINOMA.

Case Clinical Information

LEFT UPPER LOBE LUNG MASS

Gross Description

A. Received in formalin labeled with the patient's name and "4R-1" are four yellow-tan fibroadipose tissue fragments measuring 0.7 x 0.5 cm. Wrapped and submitted in A1.

B. Received in formalin labeled with the patient's name and "4R-2" is yellow-tan fibroadipose tissue measuring 0.5 x 0.4 cm. Wrapped and submitted in B1.

C. Received in formalin labeled with the patient's name and "2R-1" is yellow-tan fibroadipose tissue measuring 0.5 x 0.5 cm. Wrapped and submitted in C1.

D. Received in formalin labeled with the patient's name and "2R-2" is yellow-tan fibroadipose tissue measuring 0.5 x 0.4 cm. Wrapped and submitted in D1.

E. Received in formalin labeled with the patient's name and "4L-1 FS" is a yellow-tan frozen section tissue fragment measuring 1.2 x 0.7 cm. Wrapped and submitted in E1.

F. Received in formalin labeled with the patient's name and "4L-2 FS" is yellow-tan fibroadipose tissue measuring 0.7 x 0.5 cm. Wrapped and submitted in F1.

G. Received in formalin labeled with the patient's name and "station 3 FS" are two yellow-tan fibroadipose tissue

[page 4 of 6]
fragments. The largest fragment measures 0.7 x 0.5 cm and the smaller fragment measures 0.5 x 0.4 cm. Wrapped and submitted in G1.

H. Received in formalin labeled with the patient's name and "2L-1" is yellow-tan fibroadipose tissue measuring 0.7 x 0.5 cm. Wrapped and submitted in H1.

I. Received in formalin labeled with the patient's name and "station 7 FS" are two yellow-tan fibroadipose tissue fragments measuring 0.4 x 0.4 cm. Wrapped and submitted in I1.

J. Received in formalin labeled with the patient's name and "hilar node #1" are two yellow-brown fibroadipose tissue fragments. The largest fragment measures 0.7 x 0.4 cm and the smaller fragment measures 0.4 x 0.4 cm. Wrapped and submitted in J1.

K. Received in formalin labeled with the patient's name and "hilar node #2" is a yellow-brown fibroadipose tissue fragment measuring 1.5 x 0.7 cm. Wrapped and submitted in K1.

L. Received in formalin labeled with the patient's name and "hilar node #3" is yellow-brown fibroadipose tissue measuring 0.7 x 0.4 cm. Wrapped and submitted in L1.

M. Received in formalin labeled with the patient's name and "lingular segment left upper lobe" is a previously sectioned segment of left upper lobe lung weighing 50 grams and measuring in aggregate 10 x 6 x 1.5 cm. The specimen has a staple line on one of the edges, which is removed and inked in black. The lung parenchyma is a gray-brown and spongy. No tumor is grossly identified. The specimen is represented as follows: parenchyma through the inked resection margin=M1-M4; lung parenchyma=M5. Also in the same container is an undesignated detached suture.

N. Received in formalin labeled with the patient's name and "lingular segment left upper lobe FS" are two gray-tan frozen section tissue fragments. The larger fragment measures 2 x 1.2 cm and the smaller fragment measures 1 x 0.9 cm. Wrapped and submitted in N1.

O. Received in formalin labeled with the patient's name and "station #5" is a yellow-tan fibroadipose tissue fragment measuring 2 x 1.5 cm. Wrapped and submitted in O1.

P. Received in formalin labeled with the patient's name and "extended lingular segment stitch at mass" is a wedge of lung weighing 27 grams, measuring 6 x 5 x 2.4 cm. The specimen has a staple line on one of the edges, which is removed. The specimen has been previously serially sectioned. Sectioning shows a gray-tan nodule measuring 1.4 x 1 x 0.7 cm. The remainder of the parenchyma is gray-brown and spongy, and no other lesion is grossly identified. The specimen is represented as follows: remainder of the parenchymal margin=P1; entire lesion submitted=P2-P4; parenchyma adjacent to the lesion=P5-P7; and parenchyma through the staple resection margin=P8.

P

[page 5 of 6]
Q. Received in formalin labeled with the patient's name and "extended lingular segment FS" is a gray-tan frozen section tissue fragment measuring 1.5 x 1.0 cm. Wrapped and submitted in Q1. This case was reviewed with

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. AA ROUTINE H&E X1 BLOCK
H&E X1
- D. AA ROUTINE H&E X1 BLOCK
H&E X1
- E. AA ROUTINE H&E X1 BLOCK
H&E X1
- F. AA ROUTINE H&E X1 BLOCK
H&E X1
- G. AA ROUTINE H&E X1 BLOCK
H&E X1
- H. AA ROUTINE H&E X1 BLOCK
H&E X1
- I. AA ROUTINE H&E X1 BLOCK
H&E X1
- J. AA ROUTINE H&E X1 BLOCK
H&E X1
- K. AA ROUTINE H&E X1 BLOCK
H&E X1
- L. AA ROUTINE H&E X1 BLOCK
H&E X1
- M. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- M. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- M. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- M. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- M. AA ROUTINE H&E X1 BLOCK.5
H&E X1
- N. AA ROUTINE H&E X1 BLOCK
H&E X1
- O. AA ROUTINE H&E X1 BLOCK
H&E X1
- P. AA ROUTINE H&E X1 BLOCK.1

Prepared

[page 6 of 6]
H&E X1
P. AA ROUTINE H&E X1 BLOCK.2
H&E X1
P. AA ROUTINE H&E X1 BLOCK.3
H&E X1
P. AA ROUTINE H&E X1 BLOCK.4
H&E X1
P. AA ROUTINE H&E X1 BLOCK.5
H&E X1
P. AA ROUTINE H&E X1 BLOCK.6
H&E X1
P. AA ROUTINE H&E X1 BLOCK.7
H&E X1
P. AA ROUTINE H&E X1 BLOCK.8
H&E X1
Q. AA ROUTINE H&E X1 BLOCK
H&E X1

Prepared

Metastatic/Primary		

Source: NCI Genomic Data Commons file 2c69aa26-7ead-49fd-91cf-43baa64d7188 (TCGA-J2-A4AE.DF9C8900-3277-481F-82BD-335744EABD7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).